Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4961, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4961-01A (Primary Tumor).

[page 1 of 3]
TCGA-BP-4961

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

H/O epigastric pain with incidental renal mass discovered.

Specimens Submitted:

- 1: SP: Kidney, right, partial nephrectomy
- 2: SP: Kidney, right, deep margin #2, excision
- 3: SP: Kidney, right, deep margin #3, excision
- 4: SP: Kidney, right, deep margin #4, excision

DIAGNOSIS:

1. SP: Kidney, right, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
The tumor shows focal ossification.

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Kidney, right, deep margin #2, excision

Benign blood vessel.

[page 2 of 3]
3. SP: Kidney, right, deep margin #3, excision [REDACTED]
Benign renal parenchyma.
4. SP: Kidney, right, deep margin #4, excision [REDACTED]
Benign renal parenchyma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received for frozen section, labeled "Right renal tumor". It consists of a single segment of wedge-shaped renal tissue that measures 5 x 4 x 4 cm in greatest dimension. The surgical margin of the specimen is inked black. A stitch is present on the surgical margin and this area is submitted for frozen diagnosis. The opposite aspect of the specimen reveals a large amount of fatty tissue that is grossly unremarkable. This aspect of tissue is inked blue. The tissue is cross-sectioned, revealing a bright yellow and somewhat hemorrhagic tumor lesion that measures 3.0 x 2.5 x 3.0 cm. The tumor is approximately 0.1 cm from the deep surgical margin. A sample of tumor is submitted to TPS. Grossly, the tumor is confined to the kidney. The specimen is representatively submitted.

Summary of Sections:
TUMR - Tumor sections
T - Tumor with fat

[REDACTED]

2) The specimen is received in formalin, labeled "Deep margin #2 right kidney". It consists of a single small fragment of tan tissue that measures 0.5 x 0.2 x 0.1 cm. The tissue is entirely submitted.

Summary of sections:
U - undesignated

[REDACTED]

3) The specimen is received in formalin, labeled "Deep margin #3 right kidney". It consists of two fragments of tan small tissue that measures in aggregate 0.5 x 0.2 x 0.1 cm. The tissue is entirely submitted.

Summary of sections:
U - undesignated

[REDACTED]

4) The specimen is received in formalin, labeled "Deep margin #4 right kidney". It consists of a single fragment of tan firm tissue that measures 1.0 x 0.1 x 0.2 cm. The tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Kidney, right, partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
2	fat	2
1	fsc	1
6	tumr	6

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Part 2: SP: Kidney, right, deep margin #2, excision [REDACTED]

Block	Sect. Site	PCs
1	u	1

Part 3: SP: Kidney, right, deep margin #3, excision [REDACTED]

Block	Sect. Site	PCs
1	u	1

Part 4: SP: Kidney, right, deep margin #4, excision [REDACTED]

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: STITCHED MARGIN BENIGN. FAVOR CLEAR CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: Same
- [REDACTED]

Source: NCI Genomic Data Commons file 7af23392-bb24-4340-b3a4-1f68e10ecbbf (TCGA-BP-4961.75D67C82-1B9C-4B88-A087-205C1356131A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).